Somatic mutation profile of tumor specimen TCGA-AA-3930-01A (aliquot TCGA-AA-3930-01A-01W-0995-10) from TCGA case TCGA-AA-3930, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 66.6 years (24,321 days).
Specimen TCGA-AA-3930-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1c87c0d-3b22-4e62-be6e-33e206ccfeab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3930-10A (Blood Derived Normal), aliquot TCGA-AA-3930-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08596210-4e26-43dd-9fa9-70f29c6c4abb

The open-access MAF lists 214 somatic variants for this specimen: 148 protein-altering or splice-affecting, 63 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 63, Nonsense Mutation 10, Splice Site 3, Frame Shift Ins 3, Frame Shift Del 3, RNA 2, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 21/28 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 168/332 reads (51%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC024598.1 | c.1000C>A p.H334N | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.001); catalogued as COSV67921184, COSV67923534; called by muse, mutect2, varscan2
- ACAN | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143697605, COSV61363097; called by muse, mutect2, varscan2
- ADGRV1 | c.3888G>T p.L1296F | Missense Mutation (SNP) | VAF 101/287 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101316762; called by muse, mutect2, varscan2
- ADSL | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 92/182 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV53406844; called by muse, mutect2, varscan2
- ANXA8L1 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 106/472 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.175); catalogued as rs1554975591, COSV63225737; called by muse, varscan2
- ARID1A | c.2879-1G>A p.X960_splice | Splice Site (SNP) | VAF 8/175 reads (5%) | catalogued as COSV61372173, COSV61380279; called by muse, mutect2
- ASB5 | c.649A>C p.I217L | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1191989338; called by muse, mutect2, varscan2
- ATP8A2 | c.1363G>T p.E455* | Nonsense Mutation (SNP) | VAF 114/568 reads (20%) | catalogued as COSV99679800; called by muse, mutect2, varscan2
- C1S | c.36G>A p.W12* | Nonsense Mutation (SNP) | VAF 145/235 reads (62%) | catalogued as COSV61070195; called by muse, mutect2, varscan2
- C3 | c.2522G>A p.R841Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746085199, COSV55578737, COSV99836450; called by muse, mutect2, varscan2
- CACNB2 | c.1823G>A p.R608H (on ENST00000324631 / NM_201596.3; = p.R553H on NM_000724.4) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as rs771011929, COSV56644129; called by muse, mutect2, varscan2
- CARD16 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 155/1780 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV65212750; called by muse, mutect2
- CCDC125 | c.1337dup p.N446Kfs*15 | Frame Shift Ins (INS) | VAF 39/188 reads (21%) | catalogued as rs749636669; called by mutect2, varscan2
- CHD5 | c.2267C>T p.A756V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as rs144145989; called by muse, varscan2
- CHIA | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 53/385 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs201556508, COSV58473904; called by muse, mutect2, varscan2
- CNTN1 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 96/134 reads (72%) | catalogued as COSV61640104; called by muse, mutect2, varscan2
- CRISP3 | c.826T>A p.Y276N (on ENST00000371159 / NM_001368123.1; = p.Y258N on NM_006061.4) | Missense Mutation (SNP) | VAF 73/373 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV53819228; called by muse, mutect2, varscan2
- CXCL17 | c.115T>A p.S39T | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV59408572; called by muse, mutect2, varscan2
- DENND6A | c.1337G>C p.S446T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1407911738, COSV60767742; called by muse, mutect2, varscan2
- DMXL2 | c.8176C>G p.Q2726E | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV51840667; called by muse, mutect2, varscan2
- DNAAF4 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 144/382 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as rs776607716, COSV58246939, COSV58249702; called by muse, varscan2
- DPYS | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60906723; called by muse, mutect2, varscan2
- DSCAM | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 124/348 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs367690354, COSV68648441; called by muse, mutect2, varscan2
- EFCAB14 | c.987G>A p.M329I | Missense Mutation (SNP) | VAF 107/281 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV64238185; called by muse, mutect2, varscan2
- ESX1 | c.1171A>G p.I391V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV65423971; called by muse, mutect2, varscan2
- FAP | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs373219307, COSV51859783; called by muse, mutect2, varscan2
- FIGN | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 75/295 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV60763582, COSV60766918; called by muse, mutect2, varscan2
- FUBP1 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV53934628, COSV99628394; called by muse, mutect2
- GABRG2 | c.216C>A p.N72K | Missense Mutation (SNP) | VAF 212/807 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.419); catalogued as rs768062008, COSV62715771; called by muse, mutect2, varscan2
- GATA3 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.666); catalogued as COSV60515912; called by muse, mutect2, varscan2
- GEM | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 89/176 reads (51%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs780498125, COSV52596716; called by muse, mutect2, varscan2
- GPC3 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 1223/2070 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as rs372317881, COSV63666129; called by muse, mutect2, varscan2
- HADHA | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV66106440; called by muse, mutect2, varscan2
- HFM1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs146051438; called by muse, mutect2, varscan2
- IL17RD | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 63/83 reads (76%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs770716213; called by muse, mutect2, varscan2
- ITGA5 | c.1099G>T p.V367F | Missense Mutation (SNP) | VAF 52/66 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV53217892; called by muse, mutect2, varscan2
- KCNK10 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs771917656, COSV56640159, COSV56643228; called by muse, mutect2, varscan2
- LAMB3 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs116472735; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LMNTD1 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 40/950 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as COSV51447800; called by muse, mutect2
- LY96 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs887548267, COSV53024758; called by muse, mutect2, varscan2
- MACO1 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 88/466 reads (19%) | catalogued as COSV65475160; called by muse, mutect2, varscan2
- MARCHF11 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60126559; called by muse, mutect2, varscan2
- MCF2 | c.1070A>C p.E357A | Missense Mutation (SNP) | VAF 197/324 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100644834, COSV104407467; called by muse, mutect2, varscan2
- MPDZ | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 371/1176 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.116); catalogued as rs767694605, COSV100056085; called by muse, mutect2, varscan2
- MUC16 | c.35530T>C p.S11844P | Missense Mutation (SNP) | VAF 168/600 reads (28%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.006); catalogued as rs747111472; called by muse, mutect2, varscan2
- MUC16 | c.28177C>T p.P9393S | Missense Mutation (SNP) | VAF 22/717 reads (3%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.205); catalogued as rs1377253269, COSV67472530; called by muse, mutect2
- NCAM2 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 112/287 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370033455; called by muse, mutect2, varscan2
- NEU3 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377168820; called by muse, mutect2, varscan2
- NIPAL1 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV55005885; called by muse, mutect2, varscan2
- NT5DC3 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 113/183 reads (62%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.784); catalogued as rs1478255341, COSV67323040; called by muse, mutect2, varscan2
- OIT3 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs369081761; called by muse, mutect2, varscan2
- OR10K1 | c.128C>A p.A43E | Missense Mutation (SNP) | VAF 195/724 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as COSV56870756; called by muse, mutect2, varscan2
- OR10S1 | c.412C>A p.L138M | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV73342675; called by muse, mutect2, varscan2
- OR5P3 | c.681G>C p.K227N | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as COSV60429008; called by muse, mutect2, varscan2
- OR6N1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376841145; called by muse, mutect2, varscan2
- OSBPL5 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV55139700; called by muse, mutect2, varscan2
- PCARE | c.3620C>A p.T1207N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs372010073; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHGB6 | c.1667A>G p.N556S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53906781; called by muse, mutect2
- PDCL3 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 203/634 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs763398924, COSV51808754; called by muse, mutect2
- PDE4D | c.115C>A p.H39N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV61422293; called by muse, mutect2, varscan2
- PGLYRP4 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 78/381 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.038); catalogued as COSV62834684; called by muse, mutect2, varscan2
- POLB | c.131C>T p.S44F | Missense Mutation (SNP) | VAF 61/924 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV55348348; called by muse, mutect2
- PSMD2 | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1458873339, COSV59529633; called by muse, mutect2, varscan2
- PTPN2 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 504/1581 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58995504; called by muse, mutect2, varscan2
- PYHIN1 | c.58T>C p.Y20H | Missense Mutation (SNP) | VAF 119/350 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.836); catalogued as rs1188880655; called by muse, mutect2, varscan2
- RPP38 | c.290C>G p.A97G | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV65381522; called by muse, mutect2, varscan2
- RSAD2 | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 84/460 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs771420018; called by muse, mutect2, varscan2
- SEC63 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 466/988 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs148837883; called by muse, mutect2, varscan2
- SEMA5B | c.1210C>T p.R404C | Missense Mutation (SNP) | VAF 118/365 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs771110590, COSV52090865; called by muse, mutect2, varscan2
- SGSM1 | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.14); catalogued as rs372769247, COSV68511131; called by muse, mutect2, varscan2
- SHOX | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309060961; called by muse, mutect2, varscan2
- SLC39A9 | c.301C>A p.H101N | Missense Mutation (SNP) | VAF 149/280 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.258); catalogued as COSV50362105; called by muse, mutect2, varscan2
- SLC4A7 | c.3002A>G p.K1001R | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.524); catalogued as COSV55396309, COSV55401446; called by muse, mutect2, varscan2
- STXBP6 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 185/534 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs752590093, COSV60590522; called by muse, mutect2, varscan2
- SV2C | c.1877T>C p.F626S | Missense Mutation (SNP) | VAF 286/911 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59215067; called by muse, mutect2, varscan2
- TBC1D10A | c.1406T>G p.V469G | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV53162978; called by muse, mutect2, varscan2
- TNS1 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT tolerated (0.92); PolyPhen benign (0.048); catalogued as rs754895922; called by muse, mutect2, varscan2
- TTN | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 32/239 reads (13%) | PolyPhen possibly damaging (0.855); catalogued as rs766680186, COSV60033306; called by muse, mutect2, varscan2
- UBA5 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 104/542 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53904076; called by muse, mutect2, varscan2
- UXS1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 64/1090 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.037); catalogued as rs568904103; called by muse, mutect2
- WDR26 | c.1327T>A p.F443I (on ENST00000414423 / NM_001379403.1; = p.F343I on NM_025160.7) | Missense Mutation (SNP) | VAF 90/241 reads (37%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.591); catalogued as COSV54353454; called by muse, mutect2, varscan2
- WT1 | c.1430A>G p.K477R | Missense Mutation (SNP) | VAF 257/744 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.398); catalogued as COSV60067171; called by muse, mutect2, varscan2
- ZNF234 | c.512C>G p.S171* | Nonsense Mutation (SNP) | VAF 16/69 reads (23%) | catalogued as COSV70602895; called by muse, mutect2, varscan2
- ZNF878 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 71/224 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs763085446, COSV72155913; called by muse, mutect2, varscan2
- ACVR1B | c.1261+1G>A p.X421_splice | Splice Site (SNP) | VAF 997/1388 reads (72%) | called by muse, mutect2, varscan2
- ANKDD1A | c.1283G>A p.W428* | Nonsense Mutation (SNP) | VAF 37/121 reads (31%) | called by muse, mutect2, varscan2
- APOBEC4 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 88/670 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AR | c.1673A>G p.K558R | Missense Mutation (SNP) | VAF 19/666 reads (3%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); called by muse, mutect2
- BCOR | c.1456_1459dup p.L487Hfs*13 | Frame Shift Ins (INS) | VAF 24/39 reads (62%) | called by mutect2, varscan2
- CACNA2D4 | c.2846G>T p.S949I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by mutect2, varscan2
- CD1E | c.4C>A p.L2M | Missense Mutation (SNP) | VAF 253/949 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- CDH12 | c.1756A>C p.T586P | Missense Mutation (SNP) | VAF 48/530 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2
- CNTN4 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 17/410 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL22A1 | c.382A>G p.S128G | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- COL4A1 | c.2304A>T p.E768D | Missense Mutation (SNP) | VAF 109/244 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- COL5A2 | c.4172G>C p.R1391P | Missense Mutation (SNP) | VAF 60/497 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COPA | c.1384G>A p.G462S | Missense Mutation (SNP) | VAF 26/399 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- CTSO | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DCAF7 | c.382T>C p.W128R | Missense Mutation (SNP) | VAF 72/1509 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2
- DCAF7 | c.383G>T p.W128L | Missense Mutation (SNP) | VAF 72/1506 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2
- DENND4B | c.2215C>T p.P739S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- FCRL5 | c.1115C>A p.S372* | Nonsense Mutation (SNP) | VAF 9/173 reads (5%) | called by muse, mutect2
- FHOD3 | c.2734C>T p.R912* (on ENST00000359247 / NM_001281739.3; = p.R929* on NM_025135.5) | Nonsense Mutation (SNP) | VAF 44/157 reads (28%) | called by muse, mutect2, varscan2
- FLG2 | c.878A>G p.N293S | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- GON4L | c.4076G>C p.G1359A | Missense Mutation (SNP) | VAF 33/363 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.022); called by muse, mutect2
- HDAC3 | c.712C>T p.P238S | Missense Mutation (SNP) | VAF 23/298 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); called by muse, mutect2
- ITGAM | c.37T>A p.L13I | Missense Mutation (SNP) | VAF 84/388 reads (22%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.637); called by muse, mutect2
- KLF3 | c.1010T>G p.L337R | Missense Mutation (SNP) | VAF 76/148 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- LAMA4 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- LAMB3 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- LNPK | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.333); called by muse, mutect2
- LRP2 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC43 | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MACF1 | c.11396A>T p.N3799I (on ENST00000372915; = p.N1732I on NM_012090.5) | Missense Mutation (SNP) | VAF 9/200 reads (5%) | called by muse, mutect2
- MAP1LC3B2 | c.280C>G p.P94A | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- MAP2 | c.455-2A>C p.X152_splice | Splice Site (SNP) | VAF 39/150 reads (26%) | called by muse, mutect2, varscan2
- MAPK9 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 31/456 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.152); called by muse, mutect2
- MIA3 | c.2977dup p.M993Nfs*3 | Frame Shift Ins (INS) | VAF 20/91 reads (22%) | called by mutect2, varscan2
- NSUN2 | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, varscan2
- OR13C8 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- OR8J1 | c.457T>G p.F153V | Missense Mutation (SNP) | VAF 24/397 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.292); called by muse, mutect2
- PCYT1A | c.636T>G p.D212E | Missense Mutation (SNP) | VAF 109/396 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- PDZD2 | c.5164C>T p.P1722S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- PHYHIPL | c.377del p.P126Qfs*7 | Frame Shift Del (DEL) | VAF 131/431 reads (30%) | called by mutect2, varscan2
- PI15 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 24/507 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); called by muse, mutect2
- PRAMEF2 | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT tolerated (0.96); PolyPhen benign (0.003); called by muse, mutect2
- PRKDC | c.12004A>T p.M4002L | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PWP1 | c.1458T>G p.I486M | Missense Mutation (SNP) | VAF 52/572 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.043); called by muse, mutect2
- RET | c.1972C>T p.H658Y | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- RHPN2 | c.581del p.L194Pfs*53 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, varscan2
- RIMS2 | c.1123A>G p.N375D (on ENST00000666250 / NM_001348490.2; = p.N183D on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- SCN10A | c.6A>T p.E2D | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); called by muse, mutect2
- SLC41A3 | c.239_241dup p.L80dup | In Frame Ins (INS) | VAF 18/50 reads (36%) | called by mutect2, varscan2
- SLX4IP | c.575C>A p.T192K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by mutect2, varscan2
- SPAG1 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SPIDR | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 280/529 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- STRADA | c.599del p.H200Pfs*3 (on ENST00000336174 / NM_001363786.1; = p.H163Pfs*3 on NM_153335.6) | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- STRIP2 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SVEP1 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, varscan2
- TGM4 | c.887A>G p.H296R | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- USP50 | c.414A>C p.Q138H (on ENST00000616326; = p.Q129H on NM_203494.5) | Missense Mutation (SNP) | VAF 134/448 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- VANGL1 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- WASHC2C | c.3569C>G p.P1190R (on ENST00000336378; = p.P1169R on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZBTB14 | c.1229A>T p.N410I | Missense Mutation (SNP) | VAF 112/235 reads (48%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ZNF44 | c.590G>T p.G197V (on ENST00000356109 / NM_001164276.2; = p.G149V on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 129/380 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADGRB3 | c.2173C>A p.R725= | Silent (SNP) | VAF 53/125 reads (42%) | catalogued as COSV65384804; called by muse, mutect2, varscan2
- ANO5 | c.1032T>A p.P344= | Silent (SNP) | VAF 511/1473 reads (35%) | catalogued as COSV61082597; called by muse, mutect2, varscan2
- ANP32B | c.285A>G p.L95= | Silent (SNP) | VAF 99/411 reads (24%) | catalogued as COSV59586154; called by muse, mutect2, varscan2
- ARFGEF3 | c.288G>A p.Q96= | Silent (SNP) | VAF 36/836 reads (4%) | called by muse, mutect2
- ARL6IP5 | c.204G>A p.L68= | Silent (SNP) | VAF 105/302 reads (35%) | called by muse, mutect2, varscan2
- ASIC2 | c.147C>T p.F49= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs778759008, COSV63296627; called by muse, mutect2, varscan2
- BCLAF1 | c.1902G>A p.S634= | Silent (SNP) | VAF 138/548 reads (25%) | catalogued as rs770845270, COSV50356960; called by muse, mutect2, varscan2
- BHLHE41 | c.42G>T p.L14= | Silent (SNP) | VAF 17/647 reads (3%) | called by muse, mutect2
- BIRC6 | c.3318C>T p.F1106= | Silent (SNP) | VAF 92/453 reads (20%) | catalogued as COSV70196055; called by muse, mutect2, varscan2
- BPIFB4 | c.1026C>T p.V342= | Silent (SNP) | VAF 125/330 reads (38%) | catalogued as rs1454850724, COSV64950795; called by muse, mutect2, varscan2
- C20orf194 | c.516G>A p.Q172= | Silent (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- CCDC34 | c.189C>T p.T63= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs1294604427; called by muse, mutect2
- CLEC14A | c.639T>C p.S213= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV60561845; called by muse, varscan2
- CNEP1R1 | c.159T>A p.P53= (on ENST00000427478 / NM_001281789.1; = p.P70= on NM_153261.5) | Silent (SNP) | VAF 178/639 reads (28%) | catalogued as COSV66696831, COSV66696999; called by muse, mutect2, varscan2
- COL1A2 | c.2517C>T p.P839= | Silent (SNP) | VAF 100/408 reads (25%) | catalogued as COSV51953777; called by muse, mutect2, varscan2
- CTR9 | c.1584T>A p.P528= | Silent (SNP) | VAF 54/198 reads (27%) | catalogued as COSV63727965; called by muse, mutect2, varscan2
- EDNRB | c.396C>T p.T132= (on ENST00000377211 / NM_001201397.1; = p.T42= on NM_000115.5) | Silent (SNP) | VAF 134/263 reads (51%) | catalogued as COSV57519352; called by muse, mutect2, varscan2
- EPX | c.2079C>T p.I693= | Silent (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- GABRG2 | c.856A>C p.R286= (on ENST00000361925 / NM_001375343.1; = p.R246= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 88/305 reads (29%) | catalogued as COSV62715776; called by muse, mutect2, varscan2
- HAPLN1 | c.948C>T p.Y316= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs199503155, COSV57145687; called by muse, mutect2, varscan2
- HTR3E | c.975G>A p.E325= (on ENST00000415389 / NM_001256613.1; = p.E340= on NM_182589.2) | Silent (SNP) | VAF 34/150 reads (23%) | catalogued as rs779991256, COSV58945969, COSV58947693; called by muse, mutect2, varscan2
- IMMT | c.1374T>C p.S458= | Silent (SNP) | VAF 418/1018 reads (41%) | catalogued as COSV54485714; called by muse, mutect2, varscan2
- ITGAM | c.39A>G p.L13= | Silent (SNP) | VAF 85/388 reads (22%) | called by muse, mutect2
- ITPR3 | c.513G>T p.R171= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV65406275; called by muse, mutect2
- JAKMIP1 | c.1506C>T p.Y502= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs753975251, COSV51523247; called by muse, mutect2, varscan2
- KCNC2 | c.982T>C p.L328= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as rs1263750393, COSV100128080, COSV54363660; called by muse, mutect2, varscan2
- KIF1A | c.2016G>A p.E672= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV57483646; called by muse, mutect2, varscan2
- KIF20A | c.324G>A p.K108= | Silent (SNP) | VAF 14/431 reads (3%) | called by muse, mutect2
- KIT | c.1278C>A p.L426= | Silent (SNP) | VAF 28/318 reads (9%) | catalogued as COSV99855308; called by muse, mutect2
- LATS2 | c.2967C>T p.Y989= | Silent (SNP) | VAF 38/192 reads (20%) | catalogued as rs775425216, COSV66873815; called by muse, mutect2, varscan2
- LEPROT | c.126C>T p.H42= | Silent (SNP) | VAF 380/838 reads (45%) | catalogued as rs780089873, COSV60754768; called by muse, mutect2, varscan2
- MED6 | c.102A>T p.S34= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV56449626; called by muse, mutect2, varscan2
- MFAP3L | c.1215C>T p.Y405= | Silent (SNP) | VAF 248/484 reads (51%) | catalogued as rs201963500, COSV64371829; called by muse, mutect2, varscan2
- MFAP3L | c.498C>T p.V166= | Silent (SNP) | VAF 73/129 reads (57%) | catalogued as COSV64371833; called by muse, mutect2, varscan2
- MKI67 | c.8607G>A p.T2869= | Silent (SNP) | VAF 56/153 reads (37%) | catalogued as rs1305444421, COSV64072814; called by muse, mutect2, varscan2
- MRPL51 | c.93G>A p.L31= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as rs753939070, COSV99975252; called by muse, mutect2
- NLRP5 | c.1788C>T p.Y596= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as rs1417105620, COSV66762452; called by muse, mutect2, varscan2
- NNMT | c.172C>T p.L58= | Silent (SNP) | VAF 43/905 reads (5%) | catalogued as rs1223572801; called by muse, mutect2
- OGDH | c.486C>T p.P162= | Silent (SNP) | VAF 122/315 reads (39%) | catalogued as rs772301635, COSV56046204; called by muse, mutect2, varscan2
- PANK2 | c.1389G>C p.L463= (on ENST00000316562 / NM_153638.3; = p.L172= on NM_024960.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 225/892 reads (25%) | catalogued as COSV57253197; called by muse, mutect2, varscan2
- PCDHB2 | c.1527C>T p.N509= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as COSV50564330, COSV50564678; called by muse, mutect2, varscan2
- PCDHB7 | c.555C>T p.S185= | Silent (SNP) | VAF 37/113 reads (33%) | catalogued as COSV50753737; called by muse, mutect2, varscan2
- PIGB | c.1065G>A p.L355= | Silent (SNP) | VAF 15/356 reads (4%) | catalogued as rs955172080; called by muse, mutect2
- PNMA8B | c.1383G>A p.A461= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs1212627683, COSV66535876; called by muse, mutect2, varscan2
- PRC1 | c.519G>A p.E173= | Silent (SNP) | VAF 160/383 reads (42%) | catalogued as COSV62694291; called by muse, mutect2, varscan2
- PSG6 | c.1200T>G p.T400= | Silent (SNP) | VAF 73/99 reads (74%) | catalogued as COSV51830519; called by muse, mutect2, varscan2
- PXDNL | c.720G>A p.P240= | Silent (SNP) | VAF 103/248 reads (42%) | catalogued as rs752441873, COSV62476799; called by muse, mutect2, varscan2
- RAPGEF5 | c.987G>A p.K329= | Silent (SNP) | VAF 40/672 reads (6%) | called by muse, mutect2
- RARA | c.27G>A p.P9= | Silent (SNP) | VAF 49/161 reads (30%) | catalogued as rs563927918, COSV54190157; called by muse, mutect2, varscan2
- SEC31A | c.3558G>A p.L1186= (on ENST00000355196 / NM_001318120.1; = p.L1147= on NM_016211.4) | Silent (SNP) | VAF 23/834 reads (3%) | called by muse, mutect2
- SH3RF1 | c.1311G>A p.Q437= | Silent (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- SIGLEC12 | c.1044G>A p.G348= (on ENST00000291707 / NM_053003.4; = p.G230= on NM_033329.2) | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV52459771; called by muse, mutect2, varscan2
- SOGA3 | c.2466C>T p.A822= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs373602535; called by muse, mutect2, varscan2
- SYT6 | c.1116G>C p.L372= (on ENST00000610222 / NM_001366225.1; = p.L287= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 220/511 reads (43%) | catalogued as COSV65772633; called by muse, mutect2, varscan2
- TENM4 | c.8106G>A p.A2702= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs769658072, COSV53611615, COSV53621848; called by muse, mutect2, varscan2
- THOC1 | c.567C>T p.F189= | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as COSV99863525; called by muse, mutect2
- TLR4 | c.840G>C p.L280= (on ENST00000355622 / NM_138554.5; = p.L240= on NM_003266.4) | Silent (SNP) | VAF 39/182 reads (21%) | catalogued as COSV62922530; called by muse, mutect2, varscan2
- TM9SF4 | c.1827G>A p.T609= | Silent (SNP) | VAF 125/553 reads (23%) | catalogued as rs758495462, COSV54111835; called by muse, mutect2, varscan2
- TMEM14C | c.126G>A p.L42= | Silent (SNP) | VAF 52/193 reads (27%) | catalogued as rs772609101, COSV57637872; called by muse, mutect2, varscan2
- TSPAN18 | c.399C>T p.V133= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV60882631; called by muse, mutect2, varscan2
- UBR7 | c.1161C>T p.L387= | Silent (SNP) | VAF 144/617 reads (23%) | catalogued as COSV50148925; called by muse, mutect2, varscan2
- ZMYND11 | c.471G>A p.E157= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs774856120, COSV59076606; called by muse, mutect2, varscan2
- ZNF592 | c.3666C>T p.A1222= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs370924552; called by muse, mutect2, varscan2
- LINC02872 | n.171C>T | RNA (SNP) | VAF 13/32 reads (41%) | catalogued as rs750044865; called by muse, varscan2
- MACF1 | c.15832-10015G>A | Intron (SNP) | VAF 10/76 reads (13%) | catalogued as rs374253856; called by muse, varscan2
- MIR518E | n.85G>A | RNA (SNP) | VAF 19/249 reads (8%) | called by muse, mutect2
